Somatic mutation profile of tumor specimen TCGA-2G-AAKO-01A (aliquot TCGA-2G-AAKO-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAKO, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AAKO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c83ffda9-b9b9-49c1-b202-4cf8dd88c07c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAKO-10A (Blood Derived Normal), aliquot TCGA-2G-AAKO-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e61fc0a-b1cb-4bbf-8ed0-f4ff704e63cf

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1669T>G p.W557G | Missense Mutation (SNP) | VAF 12/114 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs121913235, CM005329, COSV55386440, COSV55387014, COSV55389479; ClinVar: likely pathogenic; called by muse, mutect2
- DDX3X | c.1312+1dup | Frame Shift Ins (INS) | VAF 25/201 reads (12%) | called by mutect2, pindel, varscan2
- PURG | c.603C>A p.T201= | Silent (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- ZFX | c.1698C>T p.H566= | Silent (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
